Somatic mutation profile of tumor specimen TCGA-FV-A4ZQ-01A (aliquot TCGA-FV-A4ZQ-01A-11D-A25V-10) from TCGA case TCGA-FV-A4ZQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-FV-A4ZQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d126453b-8415-408e-a3a5-4cd030ed72ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A4ZQ-10A (Blood Derived Normal), aliquot TCGA-FV-A4ZQ-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a2a0ec8-8d07-4cb4-a12e-a5bc5868626c

The open-access MAF lists 94 somatic variants for this specimen: 59 protein-altering or splice-affecting, 22 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 22, Intron 8, Nonsense Mutation 7, Splice Site 2, In Frame Del 2, 3'UTR 2, RNA 2, Splice Region 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 68/262 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAM29 | c.909T>A p.F303L | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63666271; called by muse, mutect2, varscan2
- AKAP11 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1300581503, COSV50299347; called by muse, mutect2, varscan2
- B2M | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 50/95 reads (53%) | catalogued as COSV62565489; called by mutect2, varscan2
- CACTIN | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50271057; called by muse, mutect2, varscan2
- CADM1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 123/442 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as COSV59018261; called by muse, mutect2, varscan2
- CELSR1 | c.5722G>T p.V1908L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV53087936, COSV53096104; called by muse, mutect2, varscan2
- CSMD3 | c.3357C>G p.D1119E (on ENST00000297405 / NM_001363185.1; = p.D1015E on NM_052900.3) | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV52264223; called by muse, mutect2, varscan2
- DPYSL4 | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 76/172 reads (44%) | catalogued as COSV58309089, COSV58310056; called by muse, mutect2, varscan2
- EPS8L1 | c.1785C>G p.F595L (on ENST00000201647 / NM_133180.3; = p.F468L on NM_017729.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV52384675; called by muse, mutect2, varscan2
- ERMARD | c.569G>T p.W190L | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64651190; called by muse, mutect2, varscan2
- EVPL | c.3052G>C p.E1018Q | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV56914053; called by muse, mutect2, varscan2
- EXOC5 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV61771796; called by muse, mutect2, varscan2
- FBXW7 | c.892C>A p.P298T (on ENST00000281708 / NM_001349798.2; = p.P218T on NM_018315.5) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV55892980, COSV55939441; called by muse, mutect2, varscan2
- GAD1 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs1215136344, COSV60153517; called by muse, mutect2, varscan2
- GPAM | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV62082043; called by muse, mutect2, varscan2
- GRM5 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59618735; called by muse, mutect2, varscan2
- HAPLN1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57150514; called by muse, mutect2, varscan2
- JAK2 | c.1675A>C p.I559L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV67643735; called by muse, mutect2, varscan2
- KIAA1841 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV54377410; called by muse, mutect2, varscan2
- KLHDC4 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV54510575; called by muse, mutect2, varscan2
- KPNA2 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 88/127 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV57858460; called by muse, mutect2, varscan2
- LRRIQ1 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67813601; called by muse, mutect2, varscan2
- MAB21L1 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59808017; called by muse, mutect2, varscan2
- MKI67 | c.5314A>T p.R1772W | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64075799; called by muse, mutect2, varscan2
- MN1 | c.3148A>T p.S1050C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV56560646; called by muse, varscan2
- NFASC | c.757G>A p.A253T (on ENST00000339876 / NM_001378329.1; = p.A264T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs535350909, COSV58373975, COSV99046033; called by muse, mutect2, varscan2
- NUP153 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 194/318 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV50457108; called by muse, mutect2, varscan2
- OR4A47 | c.536T>A p.M179K | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as COSV71444985; called by muse, mutect2, varscan2
- PC | c.3211G>T p.A1071S | Missense Mutation (SNP) | VAF 85/122 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58993539; called by muse, mutect2, varscan2
- PCDHB1 | c.2214C>A p.N738K | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV60632448; called by muse, mutect2, varscan2
- PLEC | c.12802T>G p.S4268A (on ENST00000322810 / NM_201380.4; = p.S4158A on NM_000445.5) | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV59672487; called by muse, mutect2, varscan2
- PUM2 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57578942; called by muse, mutect2, varscan2
- QPCT | c.267+1G>T p.X89_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV58120523; called by muse, mutect2, varscan2
- RAD51AP2 | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as COSV67588664; called by muse, mutect2, varscan2
- RPL3 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV53366208; called by muse, mutect2, varscan2
- SERPINA9 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV54076995; called by muse, mutect2, varscan2
- SH2D2A | c.35-1G>A p.X12_splice | Splice Site (SNP) | VAF 37/117 reads (32%) | catalogued as COSV63885200; called by muse, mutect2, varscan2
- SLC22A16 | c.1440C>A p.S480R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57932732; called by muse, mutect2, varscan2
- SLC30A10 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV63073863; called by muse, mutect2, varscan2
- SPAG16 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59070187; called by muse, mutect2, varscan2
- SPEG | c.6634C>T p.Q2212* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV56676262; called by muse, mutect2, varscan2
- SPTBN1 | c.3317A>G p.N1106S | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs772780138, COSV61691639; called by muse, mutect2, varscan2
- SSH2 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV52177643; called by muse, mutect2, varscan2
- TENM4 | c.6739C>T p.R2247W | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758333727, COSV53653802; called by muse, mutect2, varscan2
- TERF1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52577713, COSV52579119; called by muse, mutect2, varscan2
- TNFRSF18 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1358133653, COSV60775717; called by muse, mutect2, varscan2
- USP48 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57612778; called by muse, mutect2, varscan2
- VWA1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV58600325; called by muse, mutect2, varscan2
- WDR27 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61213402; called by muse, mutect2, varscan2
- ZNF318 | c.2338G>T p.G780* | Nonsense Mutation (SNP) | VAF 111/512 reads (22%) | catalogued as COSV58935493; called by muse, mutect2, varscan2
- ZNF512B | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53875487; called by muse, mutect2, varscan2
- CUX1 | c.674+5G>A | Splice Region (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- EBF3 | c.611del p.N204Tfs*44 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- IGHM | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.42); called by muse, mutect2, varscan2
- NRROS | c.1202_1206delinsCA p.L401_G402delinsP | In Frame Del (DEL) | VAF 40/51 reads (78%) | called by pindel, varscan2*
- REN | c.327_341del p.V110_S114del | In Frame Del (DEL) | VAF 15/101 reads (15%) | called by mutect2, pindel
- TNNI2 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOH | c.906T>C p.N302= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV52773958; called by muse, mutect2, varscan2
- AXIN1 | c.75G>T p.V25= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV51990725; called by muse, mutect2, varscan2
- CRYBG1 | c.3876G>T p.P1292= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs199971648, COSV64813853; called by muse, mutect2, varscan2
- DIDO1 | c.4404G>T p.A1468= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as rs776072192, COSV56630307; called by muse, mutect2, varscan2
- FRAS1 | c.240C>T p.A80= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV53632170; called by muse, mutect2, varscan2
- HERC6 | c.948A>G p.P316= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs1282523298, COSV52032891; called by muse, varscan2
- IKZF2 | c.561C>T p.L187= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1284713718, COSV59576503; called by muse, mutect2, varscan2
- JAK3 | c.1725G>A p.L575= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV71686917; called by mutect2, varscan2
- KDM3A | c.2604G>A p.T868= | Silent (SNP) | VAF 48/163 reads (29%) | catalogued as rs771659588, COSV57224282; called by muse, mutect2, varscan2
- KLHL6 | c.1599G>C p.P533= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as rs932157964, COSV58068377; called by muse, mutect2, varscan2
- MANBA | c.1413T>C p.D471= (on ENST00000642252; = p.D425= on NM_005908.4) | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV56968687; called by muse, mutect2, varscan2
- MYH15 | c.1050C>A p.I350= | Silent (SNP) | VAF 62/111 reads (56%) | catalogued as COSV56316037; called by muse, mutect2, varscan2
- NFU1 | c.420A>T p.T140= (on ENST00000410022 / NM_001002755.4; = p.T116= on NM_015700.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/198 reads (24%) | catalogued as rs768949114, COSV58007196; ClinVar: likely benign; called by muse, mutect2, varscan2
- OGN | c.414T>C p.D138= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as COSV52761540; called by muse, mutect2, varscan2
- PSG4 | c.921T>C p.P307= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs545983733, COSV54938600; called by muse, mutect2, varscan2
- PTPRT | c.1236C>T p.Y412= | Silent (SNP) | VAF 23/226 reads (10%) | catalogued as rs376152261, COSV62000894; called by muse, mutect2
- RAB27A | c.123A>T p.T41= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100389130, COSV61017148; called by muse, mutect2, varscan2
- SIPA1L1 | c.4311C>T p.F1437= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs760762758, COSV62172319; called by muse, mutect2, varscan2
- TCTEX1D1 | c.306C>T p.L102= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV51076460; called by muse, mutect2, varscan2
- THAP11 | c.627G>T p.S209= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54646950; called by mutect2, varscan2
- TRPS1 | c.3024T>C p.G1008= (on ENST00000220888 / NM_001330599.2; = p.G1021= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/280 reads (14%) | catalogued as COSV55254496; called by muse, mutect2, varscan2
- USH2A | c.7656C>T p.T2552= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs373383107, COSV100230890; called by muse, mutect2, varscan2
- CDH23 | c.3369+414G>T | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- DCLK1 | c.2058+5161G>C | Intron (SNP) | VAF 72/236 reads (31%) | called by muse, mutect2, varscan2
- ENHO | c.-105G>A | 5'UTR (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99646543; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1863C>T | Intron (SNP) | VAF 73/216 reads (34%) | catalogued as COSV65798135; called by muse, mutect2, varscan2
- FUT9 | c.*997C>T | 3'UTR (SNP) | VAF 15/45 reads (33%) | catalogued as rs968896941, COSV100133032; called by muse, mutect2, varscan2
- KIR3DX1 | n.653G>T | RNA (SNP) | VAF 18/114 reads (16%) | catalogued as COSV55599943; called by muse, mutect2, varscan2
- KLC1 | c.1650+7655A>G | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as COSV55810052; called by muse, mutect2, varscan2
- KLHL5 | c.2211+24del | Intron (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- MAP4K4 | c.1867-947A>G | Intron (SNP) | VAF 42/143 reads (29%) | catalogued as COSV56337133; called by muse, mutect2, varscan2
- MIR892B | n.47A>T | RNA (SNP) | VAF 99/161 reads (61%) | called by muse, mutect2, varscan2
- NET1 | c.256-5051A>T | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as COSV61792194; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6862T>A | Intron (SNP) | VAF 32/78 reads (41%) | catalogued as COSV57128288; called by muse, mutect2, varscan2
- ZXDB | c.*1260A>G | 3'UTR (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100885767; called by muse, mutect2, varscan2
